Somatic mutation profile of tumor specimen MP2PRT-PAVFPS-TMP1-A (aliquot MP2PRT-PAVFPS-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVFPS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,044 days).
Specimen MP2PRT-PAVFPS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e742e4e-8932-4c61-86b7-fa2c168efdf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFPS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFPS-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d560704-649e-4190-b436-941be14eb8e1

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs368068067; called by muse, mutect2
- CYP27C1 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 162/451 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs754918379, COSV58868113; called by muse, mutect2, varscan2
- DNAH1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs377099238; called by muse, mutect2
- MMRN2 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 34/1181 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1166324242, COSV64400692; called by muse, mutect2
- MSI1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 30/761 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1210006090; called by muse, mutect2
- NUP210L | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 151/387 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs758367850, COSV55147828; called by muse, mutect2, varscan2
- PLEKHA4 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 27/627 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV54361401, COSV54366372; called by muse, mutect2
- ARHGAP28 | c.2135T>A p.V712E (on ENST00000383472 / NM_001366230.1; = p.V553E on NM_001010000.3) | Missense Mutation (SNP) | VAF 49/488 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MB21D2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PCDHB10 | c.2058C>A p.D686E | Missense Mutation (SNP) | VAF 48/808 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.176); called by muse, mutect2
- SIGLEC10 | c.811T>C p.F271L | Missense Mutation (SNP) | VAF 14/504 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2
- SLC2A10 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 20/606 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SPOCD1 | c.1703C>G p.P568R | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- USP44 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- AADAT | c.354A>G p.Q118= | Silent (SNP) | VAF 99/395 reads (25%) | catalogued as rs368592471; called by muse, mutect2, varscan2
- C2orf16 | c.768G>A p.L256= | Silent (SNP) | VAF 124/244 reads (51%) | catalogued as rs754873095, COSV68646935; called by muse, mutect2, varscan2
- FAM50B | c.393C>T p.A131= | Silent (SNP) | VAF 53/819 reads (6%) | catalogued as rs778167500; called by muse, mutect2
- PRF1 | c.147C>T p.D49= | Silent (SNP) | VAF 209/824 reads (25%) | catalogued as rs761310644; called by muse, mutect2, varscan2
- FRMD1 | chr6:168081406 G>A | 5'Flank (SNP) | VAF 174/637 reads (27%) | catalogued as rs910464604; called by muse, mutect2, varscan2
